Surgical pathology report (de-identified scan), TCGA case TCGA-W4-A7U3, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of North Carolina, specimen TCGA-W4-A7U3-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Testicle, left, radical orchiectomy

Histologic tumor type: Mixed germ cell tumor (approximately 60% teratoma, mature and immature, 20% yolk sac tumor, 10% embryonal carcinoma, 10% choriocarcinoma); see comment.

Tumor size (greatest dimension): 6.6 cm

Extent of tumor invasion:

Epididymis: Negative for malignancy

Tunica vaginalis: Negative for malignancy

Spermatic cord: Negative for malignancy

Paratesticular soft tissues: Negative for malignancy

Lymphovascular: Not identified

Histologic assessment of surgical margins, including spermatic cord margin:

Surgical margins free of tumor

Presence/absence of intratubular germ cell neoplasia: Present

Other significant findings: Mild chronic inflammation

AJCC Staging: pT1 pNx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Comment:

Drs. have reviewed this specimen and concur.

Immunohistochemical stains are performed and demonstrate diffuse positivity for cytokeratin AE1/AE3, particularly in the epithelial components of the teratoma, while the embryonal component shows positivity for CD30, and PLAP, the choriocarcinoma component showing positivity for HCG and HPL with the yolk sac component showing positivity for AFP. No staining with CD117 (cKIT) is seen.

[page 2 of 3]
Clinical History:

year-old male with a left testicular mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left testicle, spermatic cord."

Specimen fixation: formalin

Type of specimen: radical, left

Size of specimen: 9.0 x 7.5 x 5.5 cm, 165.0 grams

Structures attached to testis: epididymis, spermatic cord, tunica vaginalis

Orientation: inked blue entirely

Tumor description: Variegated tan to red, predominantly solid but with a microcystic component, with focal areas of necrosis and hemorrhage and punctate white solid areas. There are focal areas of myxoid change within the tumor.

Tumor size: 6.2 x 6.6 x 5.2 cm

Confinement/non-confinement to the tunica albuginea: confined

Focality of tumor: unifocal

Relationship of tumor to adjacent anatomic structures:

Epididymis: not grossly involved

Tunica vaginalis: not grossly involved

Paratesticular soft tissues: absent; The tunica vaginalis is loosely adhered to the epididymis.

Distance of tumor from surgical margins, including spermatic cord margin:

Spermatic cord: 10.2 cm

Tunica vaginalis: 0.2 cm (freely movable)

Tunica albuginea: abutting, bulging, but not invading

Description of remainder of tissue: The uninvolved parenchyma is tan/brown, stringy, compressed without additional mass lesions. The spermatic cord is 8.7 cm long x 1.4 cm in diameter, without any lesions.

[page 3 of 3]
Tissue submitted for special investigations: yes; tumor

Digital photograph taken: no

Block Summary:

(Inking: tunica vaginalis=blue)

A1 - spermatic cord margin

A2 - epididymis with uninvolved parenchyma and tunica vaginalis (blue)

A3 - tunica vaginalis

A4-A10 - representative sections of tumor, with respect to tunica vaginalis and epididymis in A4, respect to bulging tunica albuginea in A5, with respect to uninvolved parenchyma in A7.

9/24/13

Source: NCI Genomic Data Commons file 80164667-66a5-4782-a017-46d3bce6b34a (TCGA-W4-A7U3.EE15747F-E950-4B9E-A39A-726174CE2869.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).